Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8291, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8291-01A (Primary Tumor).

[page 1 of 6]
--	--

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Antrum Tumor size: 3.5 x 3 x 1.5 cm Tumor features: Diffusely infiltrating (linitus plastica) Histologic type: Adenocarcinoma, diffuse type Histologic grade: Not specified Tumor extent: Subserosa Lymph nodes: 1/6 positive for metastasis (Intraabdominal 1/6) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 6]
Laterality		ID

[page 5 of 6]
Excision date		Case ID	

Source: NCI Genomic Data Commons file da495e17-b038-4b2e-8448-88722d821c06 (TCGA-BR-8291.1D259742-9C4A-414A-BFEF-2D92D859A99F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).